Somatic mutation profile of tumor specimen TARGET-20-PARJRG-04A (aliquot TARGET-20-PARJRG-04A-01D) from TARGET case TARGET-20-PARJRG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,878 days).
Specimen TARGET-20-PARJRG-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef37a7ce-cbf9-47aa-be38-03692376614f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARJRG-14A (Bone Marrow Normal), aliquot TARGET-20-PARJRG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0f91cb9-8132-4675-9ea1-c769552cf44b

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF814 | c.*1284_*1286del | 3'UTR (DEL) | VAF 46/181 reads (25%) | called by mutect2, pindel, varscan2
